Somatic mutation profile of tumor specimen C3L-06925-01 (aliquot CPT0423140006) from CPTAC case C3L-06925, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 75.2 years (27,475 days).
Specimen C3L-06925-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0f12ac0-bc1d-4388-8dc6-b2e479ee45f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06925-31 (Blood Derived Normal), aliquot CPT0423130005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b82d7e71-4ab6-4d26-8a11-9b8cb986a5e9

The open-access MAF lists 1,351 somatic variants for this specimen: 1,020 protein-altering or splice-affecting, 277 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 980, Silent 277, Intron 33, Nonsense Mutation 21, Splice Region 6, Nonstop Mutation 6, 3'UTR 6, 5'Flank 6, 3'Flank 5, Frame Shift Del 3, 5'UTR 2, Frame Shift Ins 2.

Variants (750 of 1,351; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC092143.1 | c.2290G>A p.D764N | Missense Mutation (SNP) | VAF 30/466 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs267607164, CM100192, CM107338, COSV59248456; ClinVar: pathogenic; called by muse, mutect2
- BRAF | c.1923A>C p.K641N (on ENST00000288602 / NM_001374244.1; = p.K601N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs121913365, COSV56057324, COSV56058093, COSV56255469; ClinVar: likely pathogenic; called by muse, mutect2
- MYOC | c.1430T>A p.I477N | Missense Mutation (SNP) | VAF 28/345 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs74315331, CM971026, CM981352; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 20/198 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABCA13 | c.10130A>C p.K3377T | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV101447179; called by muse, mutect2
- ABCA2 | c.1706C>T p.P569L (on ENST00000614293; = p.P539L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/404 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.065); catalogued as rs773180113; called by muse, mutect2
- ABCC11 | c.2812T>C p.S938P | Missense Mutation (SNP) | VAF 36/321 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV62324790; called by muse, mutect2, varscan2
- ADAM23 | c.1497A>G p.L499= | Splice Region (SNP) | VAF 24/268 reads (9%) | catalogued as rs574485280; called by muse, mutect2
- ADAMTS7 | c.1786C>T p.R596C | Missense Mutation (SNP) | VAF 36/364 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as rs751603055, COSV101183242, COSV66308080; called by muse, mutect2
- ADAMTS9 | c.1943A>C p.D648A | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99898914; called by muse, mutect2
- ADAMTSL3 | c.1729A>G p.S577G | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs750289383; called by muse, mutect2
- ADAMTSL4 | c.1793T>A p.V598D | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV55002236; called by muse, mutect2
- ADGRB3 | c.3124T>G p.L1042V | Missense Mutation (SNP) | VAF 21/227 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.191); catalogued as rs1031555745; called by muse, mutect2
- ADGRE1 | c.1996G>A p.A666T | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770808541, COSV51672002; called by muse, mutect2, varscan2
- ALG1L2 | c.532T>C p.F178L | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753340365; called by muse, mutect2, varscan2
- APOB | c.4411T>G p.L1471V | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV51955292; called by muse, mutect2, varscan2
- ARHGAP24 | c.1733G>A p.C578Y (on ENST00000395184 / NM_001025616.3; = p.C485Y on NM_031305.3) | Missense Mutation (SNP) | VAF 30/460 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.823); catalogued as rs1330897736; called by muse, mutect2
- ARHGAP6 | c.2860C>T p.R954C (on ENST00000337414 / NM_013427.3; = p.R751C on NM_013423.3) | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs960794139; called by muse, mutect2, varscan2
- ARHGEF10 | c.3932A>G p.K1311R (on ENST00000398564; = p.K1286R on NM_014629.4) | Missense Mutation (SNP) | VAF 55/492 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1166879255; called by muse, mutect2, varscan2
- ASXL2 | c.4253A>G p.H1418R | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779368997; called by muse, mutect2
- ATRNL1 | c.3787C>T p.R1263W | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs377484564, COSV58096445; called by muse, mutect2
- ATXN10 | c.835T>G p.F279V | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs779910802; called by muse, mutect2, varscan2
- BDNF | c.201A>G p.I67M | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as rs955606495; called by muse, mutect2
- BRINP1 | c.1565A>G p.K522R | Missense Mutation (SNP) | VAF 53/353 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as COSV56301968, COSV56315208; called by muse, mutect2, varscan2
- BSN | c.8236G>A p.G2746S | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT tolerated (0.9); PolyPhen benign (0.07); catalogued as rs755150614; called by muse, mutect2, varscan2
- BTNL9 | c.314A>C p.K105T | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as rs1379190995; called by muse, mutect2
- C18orf25 | c.209A>C p.Q70P | Missense Mutation (SNP) | VAF 22/259 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs775029954; called by muse, mutect2
- C20orf194 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 24/335 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1336336891, COSV52699213; called by muse, mutect2
- CALB2 | c.130T>G p.F44V | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56939129; called by muse, mutect2
- CASR | c.2006C>T p.A669V (on ENST00000490131; = p.A746V on NM_000388.4) | Missense Mutation (SNP) | VAF 38/356 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs139417576, CM165801; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC177 | c.1133A>G p.E378G | Missense Mutation (SNP) | VAF 41/460 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs919368673; called by muse, mutect2
- CCNF | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 22/399 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1285208612; called by muse, mutect2
- CCR3 | c.830A>C p.K277T | Missense Mutation (SNP) | VAF 30/432 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.833); catalogued as COSV62463452; called by muse, mutect2
- CEP295 | c.4366T>G p.L1456V | Missense Mutation (SNP) | VAF 31/338 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.297); catalogued as rs1381314392; called by muse, mutect2
- CHPF2 | c.1852T>G p.F618V | Missense Mutation (SNP) | VAF 32/500 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761117775; called by muse, mutect2
- CLCN1 | c.440A>G p.K147R | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.697); catalogued as rs890873529; called by muse, mutect2
- CLIC5 | c.1004T>C p.L335P (on ENST00000185206 / NM_001370649.1; = p.L176P on NM_016929.5) | Missense Mutation (SNP) | VAF 32/375 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99485742; called by muse, mutect2
- CLUL1 | c.376A>G p.R126G | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs993785601; called by muse, mutect2
- CMTR1 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs375243314; called by muse, mutect2
- CNTRL | c.2229A>C p.E743D | Missense Mutation (SNP) | VAF 23/330 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV53043968; called by muse, mutect2
- COL1A1 | c.1966G>A p.G656S | Missense Mutation (SNP) | VAF 29/418 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72651629, CM970347; called by muse, mutect2
- CPEB1 | c.34dup p.C12Lfs*9 | Frame Shift Ins (INS) | VAF 30/274 reads (11%) | catalogued as rs1271064291; called by mutect2, varscan2
- CUEDC2 | c.557A>G p.K186R | Missense Mutation (SNP) | VAF 26/353 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as rs1416566612; called by muse, mutect2
- DACT3 | c.1606G>A p.G536R | Missense Mutation (SNP) | VAF 18/613 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1463610848; called by muse, mutect2
- DCLK1 | c.1100A>G p.E367G | Missense Mutation (SNP) | VAF 41/349 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1399390249; called by muse, mutect2, varscan2
- DHX38 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 44/424 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV51696740; called by muse, mutect2, varscan2
- DLX1 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 44/390 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as rs779074889; called by muse, mutect2, varscan2
- DNAAF5 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 56/333 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs1363128836; called by muse, varscan2
- DNAH10 | c.10724A>G p.K3575R (on ENST00000409039; = p.K3514R on NM_207437.3) | Missense Mutation (SNP) | VAF 34/534 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as rs1321086210; called by muse, mutect2
- DNAH6 | c.11340T>G p.D3780E | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV52852604; called by muse, mutect2, varscan2
- DNAJC1 | c.611T>G p.L204R | Missense Mutation (SNP) | VAF 22/267 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as rs1197987706; called by muse, mutect2
- DPM1 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 32/430 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1230987783, COSV99724511; called by muse, mutect2
- ELOVL4 | c.16T>C p.S6P | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.019); catalogued as rs1172450921; called by muse, mutect2
- ELP1 | c.2790T>G p.N930K | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV65897482; called by muse, mutect2
- EPHA5 | c.2933A>C p.K978T | Missense Mutation (SNP) | VAF 42/309 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV56639128, COSV56661877, COSV56681464; called by muse, mutect2, varscan2
- ERMP1 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 58/348 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as rs150106740; called by muse, mutect2, varscan2
- FAM180A | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 42/470 reads (9%) | catalogued as rs768070371; called by muse, mutect2
- FAM237A | c.257A>C p.K86T | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as rs1293872700; called by muse, mutect2
- FASTKD3 | c.881A>C p.K294T | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV52943480; called by muse, mutect2
- FBLL1 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as rs781612353, COSV57924107; called by muse, mutect2, varscan2
- FBLN2 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 64/455 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766937512; called by muse, mutect2, varscan2
- FKBP7 | c.520T>A p.L174M | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV51845951; called by muse, mutect2, varscan2
- FRMD1 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 41/409 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs371701184; called by muse, mutect2, varscan2
- GANC | c.441A>C p.E147D | Missense Mutation (SNP) | VAF 18/370 reads (5%) | PolyPhen benign (0); catalogued as COSV58808448; called by muse, mutect2
- GJC2 | c.1187G>A p.S396N | Missense Mutation (SNP) | VAF 67/473 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs932326557; called by muse, mutect2, varscan2
- GLI2 | c.4046T>G p.F1349C (on ENST00000361492 / NM_001374353.1; = p.F1366C on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/478 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as rs1223136757; called by muse, mutect2
- GPR68 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 48/494 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs774987554; called by muse, mutect2, varscan2
- GPRC5C | c.991G>A p.A331T (on ENST00000652232; = p.A286T on NM_018653.4) | Missense Mutation (SNP) | VAF 49/424 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.171); catalogued as rs957751466, COSV61236606; called by muse, mutect2, varscan2
- GSTT2B | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 42/448 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.161); catalogued as rs1449546830; called by muse, mutect2
- GTPBP2 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 28/329 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.02); catalogued as rs1268277415; called by muse, mutect2
- H2BE1 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 74/478 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs766451747; called by muse, varscan2
- HDAC3 | c.851A>G p.K284R | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.346); catalogued as rs1319308191; called by muse, mutect2
- HOXB9 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 57/383 reads (15%) | catalogued as COSV60816887; called by muse, mutect2, varscan2
- HR | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 44/400 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs1168393492; called by muse, mutect2
- HTR3A | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55471131; called by muse, mutect2
- ICA1 | c.607A>C p.K203Q | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV55576434; called by mutect2, varscan2
- IMMP2L | c.488T>G p.L163R | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs750458038; called by muse, mutect2, varscan2
- INAVA | c.1964A>T p.E655V | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100950112; called by muse, mutect2, varscan2
- INTS1 | c.290T>G p.V97G | Missense Mutation (SNP) | VAF 41/466 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1233144297; called by muse, mutect2
- ITPR1 | c.5321G>A p.G1774E (on ENST00000354582; = p.G1719E on NM_002222.7) | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as rs1202441335; called by muse, mutect2, varscan2
- IWS1 | c.2419G>A p.A807T | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54871739; called by muse, mutect2, varscan2
- KALRN | c.7317A>T p.K2439N (on ENST00000360013 / NM_001024660.4; = p.K742N on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1383181904; called by muse, mutect2
- KCNH1 | c.1079G>A p.R360H (on ENST00000271751 / NM_172362.3; = p.R333H on NM_002238.4) | Missense Mutation (SNP) | VAF 36/333 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55078571; called by muse, mutect2, varscan2
- KCNQ5 | c.838T>C p.S280P | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV59649887; called by muse, mutect2
- KIF4B | c.2424A>C p.Q808H | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV70529115; called by muse, mutect2
- KNDC1 | c.2702A>G p.Q901R | Missense Mutation (SNP) | VAF 28/383 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1261627929; called by muse, mutect2
- KRTAP21-1 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 43/616 reads (7%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.625); catalogued as COSV58646563; called by muse, mutect2
- LINGO1 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 46/411 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs199976207; called by muse, varscan2
- LRRC7 | c.833A>T p.N278I (on ENST00000651989 / NM_001370785.2; = p.N245I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50409045; called by muse, mutect2, varscan2
- LRRIQ4 | c.109T>G p.L37V | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100540434; called by muse, mutect2
- LRTM1 | c.235T>G p.L79V | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55523457; called by muse, mutect2
- LTA4H | c.851T>C p.L284P | Missense Mutation (SNP) | VAF 21/256 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57384285; called by muse, mutect2
- MAGEC3 | c.1904T>G p.V635G | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV100025355; called by muse, mutect2, varscan2
- MCC | c.874C>G p.P292A | Missense Mutation (SNP) | VAF 17/317 reads (5%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.956); catalogued as rs912111123; called by muse, mutect2
- MEN1 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.908); catalogued as rs1242887389; ClinVar: uncertain significance; called by muse, mutect2
- MICALL2 | c.2248C>T p.R750W | Missense Mutation (SNP) | VAF 86/453 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs773308322, COSV99876342; called by muse, mutect2, varscan2
- MIDN | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 66/574 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs148644773; called by muse, varscan2
- MSN | c.1366T>G p.L456V | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.513); catalogued as COSV104421151; called by muse, mutect2, varscan2
- MUC16 | c.18874A>G p.T6292A | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.012); catalogued as COSV104432147; called by muse, mutect2
- MUC17 | c.7056T>G p.S2352R | Missense Mutation (SNP) | VAF 48/351 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs761274442, COSV60302232; called by muse, mutect2, varscan2
- MUC5B | c.12937A>G p.S4313G | Missense Mutation (SNP) | VAF 62/549 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV101500021; called by muse, mutect2, varscan2
- MUC5B | c.17129T>G p.V5710G | Missense Mutation (SNP) | VAF 40/409 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs201590596, COSV71589899; called by muse, mutect2, varscan2
- MYO5A | c.354T>G p.I118M | Missense Mutation (SNP) | VAF 21/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs747516586; called by muse, mutect2
- NAV1 | c.605A>G p.E202G | Missense Mutation (SNP) | VAF 32/492 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs1183780627; called by muse, mutect2
- NEDD4 | c.3713A>C p.K1238T (on ENST00000508342 / NM_001284338.1; = p.K819T on NM_006154.4) | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs764544014; called by muse, mutect2, varscan2
- NEDD4 | c.2128T>G p.L710V (on ENST00000508342 / NM_001284338.1; = p.L291V on NM_006154.4) | Missense Mutation (SNP) | VAF 32/394 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV59062045, COSV59067307; called by muse, mutect2
- NLRP14 | c.1367A>C p.D456A | Missense Mutation (SNP) | VAF 40/395 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV55066782; called by muse, mutect2
- NPY | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 64/435 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54214956; called by muse, mutect2, varscan2
- NR1D1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 38/422 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99225439; called by muse, mutect2
- NR3C2 | c.787A>G p.S263G | Missense Mutation (SNP) | VAF 37/421 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as rs754143223, COSV60987246; called by muse, mutect2
- NT5M | c.407T>G p.F136C | Missense Mutation (SNP) | VAF 25/272 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1567889828; called by muse, mutect2
- NTNG2 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 31/339 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771334327; called by muse, mutect2
- OR10H1 | c.280T>C p.F94L | Missense Mutation (SNP) | VAF 51/466 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as rs908067741; called by muse, varscan2
- OR1J2 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 39/485 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58944458; called by muse, mutect2
- OR1R1P | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 28/333 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs1380250912; called by muse, mutect2
- OR2AP1 | c.930A>C p.*310Yext*3 | Nonstop Mutation (SNP) | VAF 12/148 reads (8%) | catalogued as COSV104396152; called by muse, mutect2
- OR4X2 | c.566T>C p.L189P | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56582075; called by muse, mutect2
- OR6C6 | c.495T>A p.D165E | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.075); catalogued as rs1359496898; called by muse, mutect2
- OTX2 | c.98-4G>A | Splice Region (SNP) | VAF 27/325 reads (8%) | catalogued as rs780106127, COSV59765776; called by muse, mutect2
- PAK2 | c.1348A>G p.R450G | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1450272505, COSV59085083; called by muse, mutect2
- PCDH11X | c.749A>C p.K250T | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV53490826, COSV53497035; called by muse, mutect2, varscan2
- PCDH12 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 62/371 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.351); catalogued as COSV51521222; called by muse, mutect2, varscan2
- PCDH17 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs1264648591, COSV64978598; called by muse, mutect2
- PCDHA12 | c.907A>G p.R303G | Missense Mutation (SNP) | VAF 59/312 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV100247403; called by muse, mutect2, varscan2
- PEG3 | c.3433A>C p.I1145L | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV99690954; called by muse, mutect2
- PEX6 | c.2482C>T p.Q828* | Nonsense Mutation (SNP) | VAF 18/190 reads (9%) | catalogued as rs267608243, CM100016; called by muse, mutect2
- PHF7 | c.1003T>G p.L335V | Missense Mutation (SNP) | VAF 31/332 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.142); catalogued as COSV59981260; called by muse, mutect2, varscan2
- PI4KA | c.2088T>G p.D696E | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.138); catalogued as rs766247199; called by muse, mutect2
- PLCE1 | c.3379A>G p.N1127D | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as CD156524; called by muse, mutect2, varscan2
- PLCG2 | c.3082T>G p.F1028V | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs71400186; called by muse, mutect2
- PLIN5 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 35/438 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs751980899, COSV101113716; called by muse, mutect2
- PLXNC1 | c.4572T>G p.I1524M | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV51582019; called by muse, mutect2
- PMS2 | c.1780T>G p.L594V | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV56220556; called by muse, mutect2
- PODXL2 | c.956A>G p.E319G | Missense Mutation (SNP) | VAF 42/428 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as COSV100686497; called by muse, mutect2
- PPP6R1 | c.880A>G p.S294G | Missense Mutation (SNP) | VAF 38/403 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.039); catalogued as rs1002658541; called by muse, mutect2
- PROKR1 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 61/490 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.067); catalogued as rs753677083, COSV58136486; called by muse, mutect2, varscan2
- PROP1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 15/246 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs1175709520; called by muse, mutect2
- PRSS55 | c.787A>G p.K263E | Missense Mutation (SNP) | VAF 30/311 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as rs1197520611; called by muse, mutect2, varscan2
- PSG2 | c.860T>G p.F287C | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV61545755; called by muse, mutect2, varscan2
- PTBP1 | c.1084G>T p.G362C (on ENST00000349038 / NM_031991.4; = p.G388C on NM_002819.5) | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100608325; called by muse, mutect2
- PTF1A | c.77T>G p.F26C | Missense Mutation (SNP) | VAF 41/441 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100919599; called by muse, mutect2
- PTPN3 | c.2231C>T p.T744M | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750440450, COSV52706432; called by muse, mutect2
- PTPRA | c.1622C>T p.T541I | Missense Mutation (SNP) | VAF 28/339 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs774890976; called by muse, mutect2
- RANBP10 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1461737287; called by muse, mutect2
- RASGRF1 | c.1016A>C p.N339T | Missense Mutation (SNP) | VAF 35/297 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69180789; called by muse, mutect2, varscan2
- RERE | c.2800A>G p.T934A | Missense Mutation (SNP) | VAF 92/493 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.527); catalogued as COSV61950338; called by muse, mutect2, varscan2
- RIMS2 | c.2555T>A p.L852H (on ENST00000666250 / NM_001348490.2; = p.L660H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51658224, COSV51706128; called by muse, mutect2
- RPS28 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 19/302 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV56846572; called by muse, mutect2
- RPS6KA4 | c.1811C>T p.S604L | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1441850972, COSV53700995; called by muse, mutect2
- RXFP2 | c.1851A>C p.Q617H | Missense Mutation (SNP) | VAF 23/366 reads (6%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as rs769168083; called by muse, mutect2
- SACS | c.11684T>A p.V3895E | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs766487632; called by muse, mutect2, varscan2
- SCEL | c.1331A>T p.N444I (on ENST00000349847 / NM_144777.3; = p.N424I on NM_003843.4) | Missense Mutation (SNP) | VAF 22/287 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.604); catalogued as COSV62993309; called by muse, mutect2
- SCN5A | c.5326A>G p.S1776G (on ENST00000333535 / NM_198056.3; = p.S1775G on NM_000335.5) | Missense Mutation (SNP) | VAF 37/416 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.104); catalogued as rs1303298205; called by muse, mutect2
- SCN5A | c.4316A>G p.Q1439R (on ENST00000333535 / NM_198056.3; = p.Q1438R on NM_000335.5) | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.103); catalogued as rs1350022850; ClinVar: uncertain significance; called by muse, mutect2
- SEC14L6 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.157); catalogued as rs1444848482; called by muse, mutect2
- SEPTIN4 | c.415T>G p.S139A | Missense Mutation (SNP) | VAF 36/482 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.234); catalogued as COSV58728295; called by muse, mutect2
- SERPINA1 | c.1207A>G p.T403A | Missense Mutation (SNP) | VAF 41/405 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.457); catalogued as rs1267334269; called by muse, mutect2, varscan2
- SH2D7 | c.1055A>G p.E352G | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs763912806; called by muse, mutect2
- SH3BP1 | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 50/438 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.027); catalogued as rs765319549; called by muse, mutect2, varscan2
- SIVA1 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764231979, COSV57331646; called by muse, mutect2, varscan2
- SLC14A2 | c.2220A>C p.Q740H | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as COSV99676261; called by muse, mutect2, varscan2
- SLC17A8 | c.493T>C p.F165L | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.009); catalogued as COSV60125112; called by muse, mutect2
- SLC19A1 | c.830A>G p.N277S | Missense Mutation (SNP) | VAF 31/454 reads (7%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.581); catalogued as rs1486330835; called by muse, mutect2
- SMAD4 | c.1601A>G p.Q534R | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV61687582; called by muse, mutect2
- SPTA1 | c.5128A>G p.K1710E | Missense Mutation (SNP) | VAF 21/355 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.674); catalogued as rs1480201954, COSV63754931; called by muse, mutect2
- STAMBP | c.374A>G p.K125R | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as rs1331580980; called by muse, mutect2, varscan2
- STK24 | c.1283A>G p.Q428R | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); catalogued as rs1374058419; called by muse, mutect2
- STK33 | c.1390T>G p.F464V | Missense Mutation (SNP) | VAF 33/301 reads (11%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV59398328; called by muse, mutect2, varscan2
- STYXL2 | c.2882A>G p.K961R | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1199586120; called by muse, mutect2
- SYNE1 | c.16645T>G p.L5549V (on ENST00000367255 / NM_182961.4; = p.L5478V on NM_033071.3) | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.618); catalogued as rs779388666; called by muse, mutect2
- TAAR9 | c.43T>C p.Y15H | Missense Mutation (SNP) | VAF 21/273 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV71512186; called by muse, mutect2
- TAS2R50 | c.841T>G p.W281G | Missense Mutation (SNP) | VAF 38/385 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1317084841; called by muse, mutect2, varscan2
- TBX5 | c.1114T>G p.S372A | Missense Mutation (SNP) | VAF 39/425 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as COSV59859498; called by muse, mutect2
- TGFBR2 | c.1141A>G p.K381E | Missense Mutation (SNP) | VAF 44/462 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55460724, COSV99846546; called by muse, mutect2
- THBD | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 39/560 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65702129; called by muse, mutect2
- TIGD4 | c.1490A>C p.N497T | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs367574043; called by muse, mutect2
- TMSB15A | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1385645847; called by muse, mutect2, varscan2
- TNNT2 | c.404A>G p.D135G | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); catalogued as rs759758840; called by muse, mutect2
- TRDN | c.1010A>C p.K337T | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.265); catalogued as COSV100522420; called by muse, mutect2
- TRIM25 | c.729A>C p.Q243H | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV100381170; called by muse, mutect2
- TSHZ2 | c.3032T>G p.L1011R | Missense Mutation (SNP) | VAF 31/406 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61588919; called by muse, mutect2
- TSPAN11 | c.698T>C p.L233P | Missense Mutation (SNP) | VAF 22/391 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1261114098; called by muse, mutect2
- TTN | c.77910A>C p.E25970D (on ENST00000591111; = p.E18546D on NM_003319.4) | Missense Mutation (SNP) | VAF 18/256 reads (7%) | PolyPhen benign (0.003); catalogued as COSV59880842; called by muse, mutect2
- UBE3B | c.2860A>G p.I954V | Missense Mutation (SNP) | VAF 25/362 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV61075099; called by muse, mutect2
- UGT2A2 | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 43/326 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs771539672, COSV99684695; called by muse, mutect2, varscan2
- UNC13B | c.4007A>C p.K1336T | Missense Mutation (SNP) | VAF 27/288 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV65935191; called by muse, mutect2, varscan2
- USP15 | c.2216G>A p.R739K (on ENST00000280377 / NM_001351159.2; = p.R710K on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.171); catalogued as rs369661902; called by muse, mutect2
- USP39 | c.203C>G p.P68R | Missense Mutation (SNP) | VAF 47/365 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs543189013; called by muse, mutect2, varscan2
- UTP23 | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 42/430 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1361949752; called by muse, mutect2
- VWA5B1 | c.1735T>G p.L579V | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.031); catalogued as COSV57056557; called by muse, varscan2
- WASHC2A | c.1669A>C p.K557Q | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1554887723; called by muse, mutect2, varscan2
- ZDBF2 | c.1166A>G p.K389R | Missense Mutation (SNP) | VAF 30/399 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as rs759326102; called by muse, mutect2
- ZNF19 | c.35A>G p.E12G | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.829); catalogued as COSV55507770; called by muse, mutect2
- ZNF479 | c.39G>T p.M13I | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as COSV100483064; called by muse, mutect2, varscan2
- ZNF57 | c.970C>T p.R324* | Nonsense Mutation (SNP) | VAF 38/339 reads (11%) | catalogued as rs1238585156; called by muse, mutect2, varscan2
- ZNF608 | c.2492A>C p.K831T | Missense Mutation (SNP) | VAF 48/427 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.974); catalogued as COSV60438768; called by muse, mutect2, varscan2
- ZNF793 | c.209A>G p.E70G | Missense Mutation (SNP) | VAF 25/405 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as rs1387098352; called by muse, mutect2
- ZNF808 | c.1192A>C p.T398P | Missense Mutation (SNP) | VAF 27/294 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63119131; called by muse, mutect2
- ZNF844 | c.1315A>G p.K439E | Missense Mutation (SNP) | VAF 33/431 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.354); catalogued as rs1568361079; called by muse, mutect2
- ZNF853 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 40/506 reads (8%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs942136150; called by muse, mutect2
- AARS1 | c.799T>G p.F267V | Missense Mutation (SNP) | VAF 14/261 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCA13 | c.2892T>G p.I964M | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ABCE1 | c.1340A>C p.K447T | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ABI3BP | c.131T>A p.L44H | Missense Mutation (SNP) | VAF 22/381 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2
- ACAD10 | c.2475G>A p.W825* | Nonsense Mutation (SNP) | VAF 24/316 reads (8%) | called by muse, mutect2
- ACOX3 | c.1930A>C p.I644L | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.028); called by muse, mutect2
- ACSF2 | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADAD1 | c.1519A>G p.S507G | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAM8 | c.1340A>T p.Q447L | Missense Mutation (SNP) | VAF 39/459 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2
- ADAMTS15 | c.2306T>C p.L769P | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ADAMTS18 | c.1088A>T p.Q363L | Missense Mutation (SNP) | VAF 26/287 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); called by muse, mutect2
- ADAMTS5 | c.1823G>A p.G608E | Missense Mutation (SNP) | VAF 33/331 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ADAR | c.1599T>G p.P533= | Splice Region (SNP) | VAF 24/244 reads (10%) | called by muse, mutect2
- ADCY3 | c.1775A>G p.E592G | Missense Mutation (SNP) | VAF 35/269 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADGRE3 | c.1834T>C p.W612R | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ADGRG3 | c.1195A>G p.S399G | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); called by muse, mutect2
- ADH7 | c.791A>C p.E264A | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2
- ADSS2 | c.588A>C p.K196N | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.163); called by muse, mutect2
- AHCTF1 | c.3430A>C p.K1144Q (on ENST00000366508; = p.K1118Q on NM_015446.5) | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- AHNAK2 | c.8846A>C p.E2949A | Missense Mutation (SNP) | VAF 49/561 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- AIFM3 | c.1352T>G p.V451G | Missense Mutation (SNP) | VAF 36/414 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- AJAP1 | c.664A>T p.T222S | Missense Mutation (SNP) | VAF 89/532 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKAP9 | c.3790A>C p.T1264P | Missense Mutation (SNP) | VAF 42/248 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- AKAP9 | c.6972A>C p.Q2324H (on ENST00000359028; = p.Q2300H on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.204); called by muse, mutect2
- ALDH4A1 | c.953A>T p.K318M | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANGPT1 | c.1492T>G p.F498V | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ANHX | c.1058A>T p.Q353L | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.559); called by muse, mutect2
- ANK2 | c.4067A>T p.K1356M | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANK2 | c.6574T>C p.S2192P | Missense Mutation (SNP) | VAF 48/417 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANK2 | c.9516A>C p.K3172N | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.466); called by muse, mutect2
- ANK3 | c.7055A>T p.K2352M | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- ANK3 | c.2142A>C p.E714D | Missense Mutation (SNP) | VAF 26/359 reads (7%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); called by muse, mutect2
- ANKRD18B | c.1219A>G p.N407D | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.301); called by muse, mutect2
- ANKRD28 | c.2480T>C p.L827P | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKRD44 | c.1153T>G p.S385A | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2
- ANO4 | c.1330T>G p.F444V (on ENST00000392977 / NM_001286615.2; = p.F409V on NM_178826.4) | Missense Mutation (SNP) | VAF 32/396 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- APAF1 | c.3599A>C p.K1200T (on ENST00000551964 / NM_181861.2; = p.K1146T on NM_001160.3) | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2
- APBA1 | c.263A>G p.H88R | Missense Mutation (SNP) | VAF 42/538 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.514); called by muse, mutect2
- APOBEC3G | c.578T>A p.L193H | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- AREL1 | c.1325A>C p.K442T | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARFGAP2 | c.1337A>C p.E446A | Missense Mutation (SNP) | VAF 28/295 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- ARFGAP3 | c.1477A>G p.R493G | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.298); called by muse, mutect2
- ARHGAP15 | c.49A>T p.T17S | Missense Mutation (SNP) | VAF 28/311 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ARHGEF12 | c.2763T>G p.C921W | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGEF28 | c.1562A>G p.E521G | Missense Mutation (SNP) | VAF 27/336 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.402); called by muse, mutect2
- ARHGEF38 | c.2071T>C p.S691P | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2
- ARHGEF40 | c.1338A>C p.K446N | Missense Mutation (SNP) | VAF 35/420 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- ARHGEF40 | c.3206C>G p.P1069R | Missense Mutation (SNP) | VAF 49/435 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ARID1A | c.3164_3165del p.Y1055Cfs*49 | Frame Shift Del (DEL) | VAF 37/204 reads (18%) | called by mutect2, pindel, varscan2
- ARSB | c.502T>C p.Y168H | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- ATM | c.5338T>G p.F1780V | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- ATMIN | c.475A>C p.M159L | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2
- ATP10D | c.2693T>C p.L898P | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP11C | c.2071T>G p.C691G | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ATP12A | c.1306T>G p.L436V | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ATP2C2 | c.2258T>C p.F753S | Missense Mutation (SNP) | VAF 25/274 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.197); called by muse, mutect2
- ATP5F1A | c.893A>G p.E298G | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.131); called by muse, mutect2
- ATP8B4 | c.2629T>G p.F877V | Missense Mutation (SNP) | VAF 18/347 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BAHCC1 | c.6670G>A p.E2224K | Missense Mutation (SNP) | VAF 40/496 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- BARX2 | c.822del p.E274Dfs*5 | Frame Shift Del (DEL) | VAF 20/222 reads (9%) | called by mutect2, pindel
- BCAP31 | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- BCOR | c.1555G>T p.E519* | Nonsense Mutation (SNP) | VAF 70/280 reads (25%) | called by muse, mutect2, varscan2
- BCOR | c.1432T>A p.S478T | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- BCOR | c.964A>G p.T322A | Missense Mutation (SNP) | VAF 55/281 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- BIRC6 | c.13571T>G p.L4524R | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2
- BNC2 | c.1232T>C p.V411A | Missense Mutation (SNP) | VAF 45/380 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- BOLA1 | c.239T>G p.L80R | Missense Mutation (SNP) | VAF 44/435 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.068); called by muse, mutect2
- BPGM | c.316A>C p.N106H | Missense Mutation (SNP) | VAF 21/314 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2
- BPI | c.874T>C p.Y292H (on ENST00000262865; = p.Y288H on NM_001725.3) | Missense Mutation (SNP) | VAF 30/397 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- BTBD11 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 25/386 reads (6%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); called by muse, mutect2
- BTBD11 | c.2543A>G p.E848G (on ENST00000280758 / NM_001018072.2; = p.E385G on NM_001017523.2) | Missense Mutation (SNP) | VAF 41/403 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- BTNL9 | c.914T>G p.L305R | Missense Mutation (SNP) | VAF 23/311 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- BTRC | c.1190T>C p.V397A (on ENST00000370187 / NM_033637.4; = p.V361A on NM_003939.5) | Missense Mutation (SNP) | VAF 28/351 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- C10orf71 | c.3533A>T p.E1178V | Missense Mutation (SNP) | VAF 44/460 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- C16orf89 | c.95A>C p.K32T | Missense Mutation (SNP) | VAF 35/302 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by mutect2, varscan2
- C17orf113 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 34/365 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.028); called by muse, mutect2
- C19orf47 | c.332A>G p.Q111R | Missense Mutation (SNP) | VAF 31/283 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- C1QL3 | c.74T>A p.L25Q | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- C1orf198 | c.575A>G p.K192R | Missense Mutation (SNP) | VAF 46/456 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C20orf85 | c.130T>G p.L44V | Missense Mutation (SNP) | VAF 19/283 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2
- C2CD5 | c.1568A>G p.K523R | Missense Mutation (SNP) | VAF 17/316 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2
- C5 | c.2575A>C p.M859L | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C7 | c.673T>G p.F225V | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.273); called by muse, mutect2
- C7 | c.1781A>C p.N594T | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.018); called by muse, mutect2
- CA8 | c.190T>C p.S64P | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- CABYR | c.301A>C p.K101Q | Missense Mutation (SNP) | VAF 13/306 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- CACNA1A | c.5881A>G p.I1961V | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.279); called by muse, mutect2
- CACNA1B | c.6611A>C p.K2204T | Missense Mutation (SNP) | VAF 45/426 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by mutect2, varscan2
- CACNA1D | c.4342T>A p.Y1448N (on ENST00000350061 / NM_001128840.3; = p.Y1468N on NM_000720.4) | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CADPS2 | c.3469A>C p.T1157P | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CAMTA2 | c.3175T>G p.F1059V | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CARD18 | c.99A>C p.E33D | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- CARS2 | c.767A>C p.E256A | Missense Mutation (SNP) | VAF 63/368 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CASP7 | c.572T>G p.L191R | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2
- CATSPERE | c.697T>A p.S233T | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.038); called by muse, mutect2
- CBWD1 | c.1170A>C p.E390D | Missense Mutation (SNP) | VAF 20/301 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2
- CCDC136 | c.93A>C p.E31D | Missense Mutation (SNP) | VAF 60/421 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCDC159 | c.388T>A p.C130S | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.034); called by muse, mutect2
- CCDC168 | c.10929T>G p.I3643M | Missense Mutation (SNP) | VAF 15/273 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); called by muse, mutect2
- CCDC168 | c.9165A>C p.E3055D | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.451); called by muse, mutect2
- CCDC168 | c.8214A>C p.K2738N | Missense Mutation (SNP) | VAF 32/405 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.147); called by muse, mutect2
- CCDC168 | c.4115T>G p.V1372G | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2
- CCDC180 | c.1526A>C p.K509T | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- CCDC180 | c.4661C>T p.S1554F | Missense Mutation (SNP) | VAF 22/359 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); called by muse, mutect2
- CCDC183 | c.1382C>T p.T461I | Missense Mutation (SNP) | VAF 21/252 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2
- CCDC60 | c.1347A>C p.E449D | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.562); called by muse, mutect2
- CCDC80 | c.2222A>C p.D741A | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCNDBP1 | c.273A>C p.Q91H | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.503); called by muse, mutect2
- CCNI | c.997T>G p.F333V | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2
- CD1C | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.023); called by muse, mutect2
- CDC42BPB | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 40/370 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.269); called by muse, mutect2
- CDCA2 | c.2600C>T p.S867F | Missense Mutation (SNP) | VAF 12/410 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2
- CDH23 | c.880A>G p.T294A | Missense Mutation (SNP) | VAF 38/308 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- CDH23 | c.3632A>G p.Q1211R | Missense Mutation (SNP) | VAF 39/349 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CDH23 | c.5636A>G p.D1879G | Missense Mutation (SNP) | VAF 37/447 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDK17 | c.1028A>C p.K343T | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDK5R2 | c.1039T>C p.S347P | Missense Mutation (SNP) | VAF 42/361 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK5RAP2 | c.4411A>G p.R1471G | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- CEMIP | c.2900A>C p.E967A | Missense Mutation (SNP) | VAF 38/385 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); called by muse, mutect2
- CENPF | c.5536T>G p.L1846V | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.233); called by muse, mutect2
- CEP164 | c.4073A>C p.E1358A | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CEP192 | c.1861T>G p.L621V | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CEP290 | c.4742T>G p.L1581R | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- CEP72 | c.187C>G p.R63G | Missense Mutation (SNP) | VAF 30/281 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- CEP97 | c.1939A>C p.S647R | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- CFAP299 | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2
- CFAP44 | c.4340T>A p.L1447H | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.929); called by muse, mutect2
- CFAP44 | c.1274T>A p.L425H | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CFAP91 | c.2222A>C p.K741T | Missense Mutation (SNP) | VAF 31/323 reads (10%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFP | c.274A>G p.T92A | Missense Mutation (SNP) | VAF 45/260 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- CHCHD3 | c.67G>T p.V23L | Missense Mutation (SNP) | VAF 39/345 reads (11%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHP2 | c.564A>C p.Q188H | Missense Mutation (SNP) | VAF 23/282 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2
- CHST2 | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 45/432 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CLEC12B | c.524A>G p.K175R | Missense Mutation (SNP) | VAF 28/289 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.013); called by muse, mutect2
- CLEC4F | c.1656A>G p.K552= | Splice Region (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
- CLK3 | c.72C>G p.S24R | Missense Mutation (SNP) | VAF 49/463 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLTCL1 | c.1427T>C p.L476P | Missense Mutation (SNP) | VAF 38/380 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CMC1 | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 27/226 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CNBP | c.87G>A p.M29I | Missense Mutation (SNP) | VAF 50/315 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTROB | c.329T>C p.L110P | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNTROB | c.453A>T p.Q151H | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.717); called by muse, mutect2
- COL1A2 | c.566A>G p.K189R | Missense Mutation (SNP) | VAF 26/330 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.556); called by muse, mutect2
- COL6A2 | c.2900A>G p.Q967R | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.74); called by muse, mutect2
- CORO7 | c.2612A>G p.E871G | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- CPEB4 | c.241A>C p.K81Q | Missense Mutation (SNP) | VAF 37/342 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CPNE7 | c.660G>A p.V220= | Splice Region (SNP) | VAF 31/354 reads (9%) | called by muse, mutect2
- CR1 | c.182T>G p.F61C | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.357); called by muse, mutect2
- CR2 | c.1537A>C p.I513L | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.031); called by muse, mutect2
- CRHBP | c.275T>C p.F92S | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- CSMD3 | c.2431T>G p.F811V (on ENST00000297405 / NM_001363185.1; = p.F707V on NM_052900.3) | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CSN1S1 | c.209A>G p.E70G | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); called by muse, mutect2
- CSNKA2IP | c.2054A>G p.E685G | Missense Mutation (SNP) | VAF 25/346 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- CST8 | c.170A>C p.N57T | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSTF2T | c.1061A>G p.Y354C | Missense Mutation (SNP) | VAF 37/345 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTHRC1 | c.95A>G p.E32G | Missense Mutation (SNP) | VAF 39/460 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2
- CTNNA1 | c.2110A>T p.K704* | Nonsense Mutation (SNP) | VAF 79/319 reads (25%) | called by muse, mutect2, varscan2
- CWF19L1 | c.869T>G p.F290C | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- CYP3A5 | c.1306A>C p.T436P | Missense Mutation (SNP) | VAF 59/389 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- DAB2 | c.18A>C p.E6D | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- DARS1 | c.1269A>C p.E423D | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DAXX | c.1149A>T p.Q383H | Missense Mutation (SNP) | VAF 29/496 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCAF6 | c.1826A>G p.E609G (on ENST00000312263 / NM_001349778.1; = p.E629G on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2
- DCANP1 | c.643T>C p.S215P | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- DCDC2C | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 40/330 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCLK2 | c.1457A>C p.K486T | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2
- DCUN1D1 | c.716T>C p.L239P | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2
- DDX60L | c.4214T>G p.I1405S | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2
- DENND3 | c.817T>G p.F273V | Missense Mutation (SNP) | VAF 21/231 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- DENND4B | c.3919T>C p.Y1307H | Missense Mutation (SNP) | VAF 17/356 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2
- DESI2 | c.158T>G p.F53C | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DHX29 | c.1833A>C p.E611D | Missense Mutation (SNP) | VAF 33/334 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- DIDO1 | c.1294G>A p.G432S | Missense Mutation (SNP) | VAF 94/389 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DIP2C | c.3823C>T p.L1275F | Missense Mutation (SNP) | VAF 34/428 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DKK2 | c.19A>G p.S7G | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- DLG5 | c.3888T>A p.H1296Q | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2
- DNAAF1 | c.1286T>G p.V429G | Missense Mutation (SNP) | VAF 58/426 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by mutect2, varscan2
- DNAH1 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 17/284 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); called by muse, mutect2
- DNAH10 | c.4712T>G p.I1571S (on ENST00000409039; = p.I1510S on NM_207437.3) | Missense Mutation (SNP) | VAF 26/303 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- DNAH10 | c.11491T>A p.S3831T (on ENST00000409039; = p.S3770T on NM_207437.3) | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2
- DNAH11 | c.2024T>G p.M675R | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- DNAH17 | c.6998T>C p.L2333P | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH17 | c.127T>A p.F43I | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH2 | c.5012A>T p.K1671M | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- DNAH3 | c.4932A>C p.Q1644H | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DNAH5 | c.2737A>G p.S913G | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- DNAH6 | c.7927T>G p.L2643V | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2
- DNAH7 | c.10785T>G p.F3595L | Missense Mutation (SNP) | VAF 29/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH9 | c.5720A>T p.N1907I | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DNAH9 | c.9692A>G p.E3231G | Missense Mutation (SNP) | VAF 28/381 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- DNAJC13 | c.3667A>C p.T1223P | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2
- DOCK3 | c.3997A>C p.I1333L | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.222); called by mutect2, varscan2
- DOK1 | c.1444T>C p.*482Rext*6 | Nonstop Mutation (SNP) | VAF 26/237 reads (11%) | called by muse, mutect2, varscan2
- DOK4 | c.955A>G p.S319G | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPP3 | c.2009A>C p.K670T | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- DUSP10 | c.692A>C p.K231T | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- DYNC1H1 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); called by muse, mutect2
- DYNC2H1 | c.3642T>A p.F1214L | Missense Mutation (SNP) | VAF 24/341 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- DYNC2H1 | c.11277A>C p.Q3759H | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- EAF2 | c.332A>C p.K111T | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- EBF4 | c.83T>C p.V28A (on ENST00000609451; = p.V24A on NM_001110514.1) | Missense Mutation (SNP) | VAF 41/423 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- ECE1 | c.416T>A p.V139D | Missense Mutation (SNP) | VAF 69/350 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ECHDC3 | c.568T>G p.L190V | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- EFR3B | c.1406A>G p.E469G | Missense Mutation (SNP) | VAF 40/325 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF4G3 | c.3050T>C p.L1017P | Missense Mutation (SNP) | VAF 45/286 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EIF5B | c.3626T>G p.L1209R | Missense Mutation (SNP) | VAF 27/305 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ELSPBP1 | c.317T>C p.F106S | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- EMILIN2 | c.1358T>C p.L453P | Missense Mutation (SNP) | VAF 40/363 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EP400 | c.2447A>G p.Q816R | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- EP400 | c.8128A>G p.I2710V | Missense Mutation (SNP) | VAF 44/335 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- ERBIN | c.2309T>G p.L770R | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- ERCC6L | c.3641G>A p.G1214E | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERICH5 | c.900A>C p.Q300H | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); called by muse, mutect2
- ERRFI1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ETNK1 | c.50T>G p.L17R | Missense Mutation (SNP) | VAF 48/654 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- ETNK2 | c.634A>G p.N212D | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2
- EVC2 | c.1728A>C p.L576F | Missense Mutation (SNP) | VAF 19/226 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2
- EXOC2 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- EYA1 | c.1658T>G p.V553G | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- F11 | c.812A>T p.K271M | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); called by muse, mutect2
- FAM102B | c.253A>G p.R85G | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM151A | c.403T>G p.S135A | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- FAM171A1 | c.2594A>G p.D865G | Missense Mutation (SNP) | VAF 33/444 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- FAM184B | c.1520A>C p.N507T | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- FAM43B | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 86/389 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- FAT2 | c.5300T>G p.I1767S | Missense Mutation (SNP) | VAF 26/369 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2
- FBN2 | c.1051A>T p.T351S | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.022); called by muse, mutect2
- FER1L6 | c.3959A>C p.K1320T | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FGF10 | c.509A>G p.Q170R | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- FKBP4 | c.383T>G p.L128R | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- FMN2 | c.4320A>C p.E1440D | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.739); called by muse, mutect2
- FMO1 | c.888A>C p.K296N | Missense Mutation (SNP) | VAF 31/376 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.928); called by muse, mutect2
- FOXA2 | c.274G>A p.G92S (on ENST00000377115 / NM_153675.3; = p.G98S on NM_021784.5) | Missense Mutation (SNP) | VAF 44/516 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.144); called by muse, mutect2
- FREM2 | c.3638T>C p.L1213P | Missense Mutation (SNP) | VAF 27/374 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FREM3 | c.1007A>C p.E336A | Missense Mutation (SNP) | VAF 34/460 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.329); called by muse, mutect2
- FRMD4A | c.1253A>C p.E418A | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- FRMD6 | c.1019A>C p.N340T (on ENST00000344768 / NM_001267046.2; = p.N332T on NM_152330.4) | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRMPD1 | c.521A>C p.N174T | Missense Mutation (SNP) | VAF 15/245 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- FRMPD4 | c.1262G>A p.G421D | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- G2E3 | c.1757A>C p.K586T | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GABRA4 | c.1109A>G p.E370G | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- GABRQ | c.1055T>G p.L352R | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- GALNT8 | c.673A>C p.N225H | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.272); called by muse, mutect2
- GARS1 | c.2178T>G p.F726L | Missense Mutation (SNP) | VAF 59/338 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GBA3 | c.1319T>G p.F440C | Missense Mutation (SNP) | VAF 42/450 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- GBX1 | c.455A>G p.E152G | Missense Mutation (SNP) | VAF 42/474 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.537); called by muse, mutect2
- GCC2 | c.1813A>C p.N605H | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.081); called by muse, mutect2
- GCH1 | c.503T>C p.L168P | Missense Mutation (SNP) | VAF 29/294 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDAP1L1 | c.1088A>C p.K363T | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- GEMIN5 | c.4106A>C p.N1369T | Missense Mutation (SNP) | VAF 38/342 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- GFPT2 | c.308A>T p.N103I | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GHR | c.1298A>C p.N433T | Missense Mutation (SNP) | VAF 22/293 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.099); called by muse, mutect2
- GIMAP8 | c.107T>G p.F36C | Missense Mutation (SNP) | VAF 48/484 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GLP2R | c.646A>G p.N216D | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLUL | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); called by muse, mutect2
- GOLGA4 | c.2280A>C p.Q760H | Missense Mutation (SNP) | VAF 23/288 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- GOT1L1 | c.734A>G p.Q245R | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); called by muse, mutect2
- GPR148 | c.344A>T p.E115V | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- GPR25 | c.416T>C p.L139P | Missense Mutation (SNP) | VAF 52/512 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, varscan2
- GPRIN1 | c.2683T>C p.S895P | Missense Mutation (SNP) | VAF 44/448 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2
- GPRIN3 | c.1975A>C p.T659P | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); called by muse, mutect2
- GREM2 | c.353A>G p.Q118R | Missense Mutation (SNP) | VAF 34/402 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.05); called by muse, mutect2
- GRIK1 | c.2501A>C p.N834T | Missense Mutation (SNP) | VAF 25/340 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- GRM5 | c.1832A>C p.K611T | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRM6 | c.592T>A p.S198T | Missense Mutation (SNP) | VAF 37/432 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- H1-8 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2
- H1-8 | c.812A>C p.K271T | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2
- H2AC15 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2
- HAO2 | c.29A>T p.Q10L | Missense Mutation (SNP) | VAF 56/312 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- HCN1 | c.2480T>C p.L827P | Missense Mutation (SNP) | VAF 21/466 reads (5%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2
- HDAC9 | c.223T>G p.L75V | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HDGFL3 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- HEATR5A | c.3869T>C p.L1290P | Missense Mutation (SNP) | VAF 18/423 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- HECW1 | c.619T>G p.F207V | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HELB | c.2432A>T p.D811V | Missense Mutation (SNP) | VAF 23/297 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.192); called by muse, mutect2
- HEPH | c.389T>C p.V130A (on ENST00000343002; = p.V184A on NM_138737.5) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HIRA | c.857A>C p.K286T | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.198); called by muse, mutect2
- HIVEP1 | c.6293A>C p.K2098T | Missense Mutation (SNP) | VAF 25/307 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HLA-A | c.710T>G p.I237S | Missense Mutation (SNP) | VAF 32/582 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HLTF | c.1358A>T p.K453M | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2
- HMCN1 | c.2977A>C p.I993L | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- HMCN1 | c.7885A>G p.R2629G | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HMCN1 | c.12632A>C p.N4211T | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.404); called by muse, mutect2
- HMGCLL1 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMGCR | c.1812A>C p.E604D | Missense Mutation (SNP) | VAF 39/377 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- HMGCS2 | c.1097A>C p.K366T | Missense Mutation (SNP) | VAF 58/380 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HMGXB3 | c.4065T>G p.C1355W (on ENST00000613459; = p.C1109W on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HMGXB4 | c.129A>C p.E43D | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- HOXC9 | c.187A>C p.S63R | Missense Mutation (SNP) | VAF 53/515 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- HRH3 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 22/235 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- HSPA14 | c.640A>C p.I214L | Missense Mutation (SNP) | VAF 36/315 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- HTR3B | c.1324T>G p.*442Gext*61 | Nonstop Mutation (SNP) | VAF 22/242 reads (9%) | called by muse, mutect2
- HTR5A | c.242_245del p.S81Wfs*15 | Frame Shift Del (DEL) | VAF 42/410 reads (10%) | called by mutect2, pindel
- IFIT2 | c.17A>C p.K6T | Missense Mutation (SNP) | VAF 21/235 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2
- IGF1 | c.281A>C p.E94A | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IGF2BP3 | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.723); called by muse, mutect2
- IGLV3-12 | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.246); called by muse, mutect2
- IGSF9B | c.2591A>T p.E864V | Missense Mutation (SNP) | VAF 40/466 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2
- IL36G | c.310A>C p.I104L | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- INHBA | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 44/219 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- INPP4A | c.521A>G p.E174G | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.167); called by muse, mutect2
- INSM2 | c.86T>A p.L29Q | Missense Mutation (SNP) | VAF 43/423 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- INSR | c.1945A>G p.N649D | Missense Mutation (SNP) | VAF 38/401 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- INTS8 | c.1647A>C p.E549D | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- IQGAP2 | c.1658A>C p.K553T | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- IRAG2 | c.862A>T p.M288L | Missense Mutation (SNP) | VAF 20/420 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- IRAK4 | c.454A>G p.S152G | Missense Mutation (SNP) | VAF 34/315 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ITGA2B | c.1193A>G p.D398G | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2
- ITIH6 | c.211T>G p.F71V | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ITPR1 | c.3723T>G p.F1241L (on ENST00000354582; = p.F1226L on NM_002222.7) | Missense Mutation (SNP) | VAF 38/422 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- JAKMIP1 | c.983A>G p.Q328R | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- JMJD1C | c.1844A>C p.K615T | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2
- JMJD1C | c.233T>C p.F78S | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- JMJD4 | c.549A>C p.K183N | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- KAT14 | c.1766T>G p.I589S | Missense Mutation (SNP) | VAF 30/377 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- KBTBD12 | c.862A>G p.R288G | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KCNE5 | c.429A>C p.*143Yext*39 | Nonstop Mutation (SNP) | VAF 29/155 reads (19%) | called by muse, mutect2, varscan2
- KCNH7 | c.1249T>G p.L417V | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.403); called by muse, mutect2
- KCNH8 | c.2342T>G p.I781S | Missense Mutation (SNP) | VAF 30/353 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- KCNQ3 | c.1403A>C p.N468T | Missense Mutation (SNP) | VAF 28/359 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2
- KCNS1 | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- KCNV1 | c.1339C>T p.Q447* | Nonsense Mutation (SNP) | VAF 40/377 reads (11%) | called by muse, mutect2, varscan2
- KDM3B | c.2818T>C p.F940L | Missense Mutation (SNP) | VAF 16/259 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2
- KDM4B | c.3086A>G p.E1029G | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2
- KIAA1549L | c.232T>C p.S78P (on ENST00000321505; = p.S375P on NM_012194.3) | Missense Mutation (SNP) | VAF 40/404 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIAA1549L | c.1834A>G p.T612A (on ENST00000321505; = p.T909A on NM_012194.3) | Missense Mutation (SNP) | VAF 40/466 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.063); called by muse, mutect2
- KIF12 | c.907T>G p.S303A (on ENST00000640217; = p.S165A on NM_138424.1) | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- KIF13A | c.2622A>C p.K874N | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- KIF4B | c.100T>G p.F34V | Missense Mutation (SNP) | VAF 34/490 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.127); called by muse, mutect2
- KIF4B | c.1856A>T p.Q619L | Missense Mutation (SNP) | VAF 16/510 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2
- KIFC1 | c.684A>T p.Q228H | Missense Mutation (SNP) | VAF 48/488 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- KLF18 | c.2074A>G p.N692D | Missense Mutation (SNP) | VAF 93/603 reads (15%) | SIFT tolerated (1); called by muse, mutect2, varscan2
- KLHL38 | c.1066T>G p.F356V | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.342); called by muse, mutect2
- KLHL40 | c.1627T>A p.F543I | Missense Mutation (SNP) | VAF 33/328 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.227); called by muse, mutect2
- KLHL9 | c.1594T>G p.L532V | Missense Mutation (SNP) | VAF 47/422 reads (11%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- KLK4 | c.748A>C p.T250P | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- KLRG2 | c.556T>C p.S186P | Missense Mutation (SNP) | VAF 52/606 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2
- KMO | c.56T>G p.V19G | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KMT2C | c.1396T>G p.L466V | Missense Mutation (SNP) | VAF 47/348 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KMT2C | c.427A>G p.S143G | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- KMT2D | c.14993A>C p.K4998T | Missense Mutation (SNP) | VAF 60/498 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KRT1 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); called by muse, mutect2
- KSR2 | c.2463A>C p.K821N | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.446); called by muse, mutect2
- L1TD1 | c.315A>G p.I105M | Missense Mutation (SNP) | VAF 61/306 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- L2HGDH | c.1306A>G p.R436G | Missense Mutation (SNP) | VAF 49/364 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- L3MBTL3 | c.1393A>T p.R465* | Nonsense Mutation (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- LAIR1 | c.545T>G p.V182G | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- LAMA4 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LARP6 | c.551A>C p.K184T | Missense Mutation (SNP) | VAF 41/400 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- LARP7 | c.942A>C p.K314N | Missense Mutation (SNP) | VAF 42/320 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- LATS1 | c.1859A>C p.N620T | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- LGMN | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- LGR6 | c.1681A>G p.S561G (on ENST00000367278 / NM_001017403.1; = p.S509G on NM_021636.3) | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2
- LHCGR | c.1334T>G p.F445C | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LHFPL5 | c.239A>C p.K80T | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- LIN7A | c.527A>C p.K176T | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LMNB1 | c.1155A>C p.E385D | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- LONRF1 | c.1589G>A p.C530Y | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); called by muse, mutect2
- LRIT1 | c.1724A>C p.E575A | Missense Mutation (SNP) | VAF 36/472 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- LRPPRC | c.927T>G p.I309M | Missense Mutation (SNP) | VAF 28/293 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2
- LRRC10B | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 52/456 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LRRC17 | c.816A>C p.K272N | Missense Mutation (SNP) | VAF 35/304 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- LRRC28 | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC46 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRRD1 | c.2529A>C p.E843D | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- LRRK2 | c.6757T>G p.F2253V | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2
- LRRTM4 | c.273T>G p.Y91* | Nonsense Mutation (SNP) | VAF 28/294 reads (10%) | called by muse, mutect2
- LSMEM1 | c.306A>C p.E102D | Missense Mutation (SNP) | VAF 46/325 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LY9 | c.958T>C p.C320R | Missense Mutation (SNP) | VAF 35/404 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.041); called by muse, mutect2
- LYST | c.8252T>G p.I2751S | Missense Mutation (SNP) | VAF 38/372 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- LYST | c.3857T>G p.L1286R | Missense Mutation (SNP) | VAF 25/254 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); called by muse, mutect2
- LYST | c.1460A>C p.K487T | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MACROD2 | c.1344A>C p.Q448H (on ENST00000642719; = p.Q420H on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.984); called by muse, mutect2
- MAGEL2 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 48/440 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- MAP2 | c.1632A>T p.K544N | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.111); called by muse, mutect2
- MAPRE3 | c.634T>G p.L212V | Missense Mutation (SNP) | VAF 17/273 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.275); called by muse, mutect2
- MAST1 | c.4369T>C p.S1457P | Missense Mutation (SNP) | VAF 41/429 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBD5 | c.1238A>G p.K413R | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- MCTP2 | c.2068A>C p.S690R | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MDFIC | c.308T>G p.L103R | Missense Mutation (SNP) | VAF 42/449 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2
- MED1 | c.4127A>C p.K1376T | Missense Mutation (SNP) | VAF 29/299 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2
- MED12 | c.5180A>G p.H1727R | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED13 | c.5425G>A p.D1809N | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MEFV | c.1250T>A p.L417Q | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- MEIOC | c.485A>C p.K162T | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- MEPE | c.1147A>G p.R383G | Missense Mutation (SNP) | VAF 32/353 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- METTL6 | c.560T>G p.F187C | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MGAM2 | c.3986A>C p.K1329T | Missense Mutation (SNP) | VAF 25/306 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2
- MGAT5B | c.1151A>C p.K384T | Missense Mutation (SNP) | VAF 33/299 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- MGLL | c.704A>G p.Q235R (on ENST00000398104 / NM_001003794.2; = p.Q245R on NM_007283.6) | Missense Mutation (SNP) | VAF 41/426 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- MIA3 | c.3995T>G p.L1332R | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MINAR1 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 36/398 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2
- MKKS | c.1587A>C p.E529D | Missense Mutation (SNP) | VAF 42/405 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MKX | c.965A>G p.D322G | Missense Mutation (SNP) | VAF 29/391 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- MLEC | c.326T>A p.F109Y | Missense Mutation (SNP) | VAF 34/418 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MMP26 | c.773C>G p.S258C | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); called by muse, mutect2
- MOS | c.559A>G p.N187D | Missense Mutation (SNP) | VAF 27/309 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.411); called by muse, mutect2
- MPO | c.141A>C p.E47D | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MROH9 | c.1144A>C p.T382P | Missense Mutation (SNP) | VAF 23/315 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.373); called by muse, mutect2
- MS4A3 | c.359A>C p.N120T | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.026); called by muse, mutect2
- MTBP | c.727A>C p.I243L | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.741); called by muse, mutect2
- MTMR3 | c.3350T>G p.L1117R | Missense Mutation (SNP) | VAF 17/289 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MTPAP | c.1536A>C p.E512D | Missense Mutation (SNP) | VAF 29/303 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, varscan2
- MTX2 | c.679T>G p.L227V | Missense Mutation (SNP) | VAF 26/311 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- MUC16 | c.30606T>G p.D10202E | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.92); called by muse, mutect2
- MUC16 | c.9887T>G p.L3296R | Missense Mutation (SNP) | VAF 39/384 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- MUC16 | c.5104T>C p.S1702P | Missense Mutation (SNP) | VAF 38/456 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); called by muse, mutect2
- MUC4 | c.5570T>C p.L1857P | Missense Mutation (SNP) | VAF 70/1075 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.774); called by muse, mutect2
- MUC5B | c.13776A>T p.K4592N | Missense Mutation (SNP) | VAF 44/458 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by mutect2, varscan2
- MYBL1 | c.1447A>C p.T483P | Missense Mutation (SNP) | VAF 25/268 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2
- MYH11 | c.3437A>G p.E1146G | Missense Mutation (SNP) | VAF 48/462 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- MYH13 | c.2702A>C p.N901T | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by muse, mutect2
- MYH4 | c.4A>G p.S2G | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- MYH7B | c.1187T>G p.I396S | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2
- MYO15A | c.5327A>G p.Q1776R | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2
- MYO18A | c.4715A>C p.K1572T | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO18A | c.2246T>C p.L749P | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2
- MYO1H | c.1472A>G p.E491G | Missense Mutation (SNP) | VAF 30/281 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); called by muse, mutect2
- MYO3B | c.2870T>G p.I957S | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO7A | c.5813A>G p.K1938R | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2
- MYOF | c.3647T>G p.F1216C | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2
- MYOF | c.2123T>C p.L708P | Missense Mutation (SNP) | VAF 21/252 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- MYOM1 | c.4261A>G p.K1421E | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2
- MYPN | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 38/366 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- NACA2 | c.44A>G p.E15G | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2
- NAGS | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 51/290 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NAMPT | c.576T>A p.D192E | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2
- NANP | c.383T>G p.L128R | Missense Mutation (SNP) | VAF 38/489 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- NAV1 | c.3580C>G p.H1194D | Missense Mutation (SNP) | VAF 41/322 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, varscan2
- NAV3 | c.2060A>C p.K687T | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NBEAL1 | c.1472T>G p.I491S | Missense Mutation (SNP) | VAF 21/341 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- NCOR1 | c.2372A>C p.E791A | Missense Mutation (SNP) | VAF 42/424 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- NCOR2 | c.7499A>T p.K2500M | Missense Mutation (SNP) | VAF 32/411 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NDN | c.799A>T p.S267C | Missense Mutation (SNP) | VAF 34/374 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- NDRG4 | c.32T>A p.L11H | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT tolerated, low confidence (0.38); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NEB | c.17396T>C p.F5799S | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- NEDD1 | c.1805A>G p.D602G | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- NEK6 | c.344A>G p.D115G | Missense Mutation (SNP) | VAF 40/392 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2
- NEK9 | c.2503T>G p.F835V | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.025); called by muse, mutect2
- NEMF | c.1152A>C p.E384D | Missense Mutation (SNP) | VAF 29/357 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2
- NEUROD4 | c.223A>T p.K75* | Nonsense Mutation (SNP) | VAF 31/340 reads (9%) | called by muse, mutect2
- NEUROG3 | c.353A>T p.K118M | Missense Mutation (SNP) | VAF 42/346 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NIBAN1 | c.376T>G p.L126V | Missense Mutation (SNP) | VAF 18/357 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.027); called by muse, mutect2
- NIN | c.2770A>C p.N924H | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.568); called by muse, mutect2
- NISCH | c.1826T>A p.L609Q | Missense Mutation (SNP) | VAF 48/398 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- NKX2-3 | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2
- NLRC3 | c.171C>A p.C57* | Nonsense Mutation (SNP) | VAF 46/290 reads (16%) | called by muse, mutect2, varscan2
- NLRP1 | c.3650T>C p.V1217A | Missense Mutation (SNP) | VAF 48/457 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NOD2 | c.293G>A p.W98* | Nonsense Mutation (SNP) | VAF 36/418 reads (9%) | called by muse, mutect2
- NODAL | c.437T>G p.F146C | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NOL8 | c.3343T>C p.F1115L | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NPHS1 | c.3443A>G p.Q1148R | Missense Mutation (SNP) | VAF 38/366 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPTX2 | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 111/581 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- NR0B1 | c.50T>G p.L17R | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- NRCAM | c.3055A>C p.N1019H (on ENST00000379028 / NM_001371124.1; = p.N1003H on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.262); called by muse, mutect2
- NRP2 | c.484T>C p.S162P | Missense Mutation (SNP) | VAF 27/364 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- NRXN3 | c.1381C>T p.P461S (on ENST00000335750 / NM_001330195.2; = p.P88S on NM_004796.6) | Missense Mutation (SNP) | VAF 25/306 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- NT5C1B | c.1359A>C p.K453N (on ENST00000359846 / NM_001199086.2; = p.K393N on NM_033253.4) | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.698); called by muse, mutect2
- NWD2 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 26/311 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OBSCN | c.12784A>C p.S4262R | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.917); called by muse, mutect2
- OGFOD1 | c.593A>C p.K198T | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); called by muse, mutect2
- OGN | c.785A>G p.Y262C | Missense Mutation (SNP) | VAF 36/404 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OPA1 | c.1984A>G p.S662G (on ENST00000361510 / NM_130837.3; = p.S607G on NM_015560.3) | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2
- OPLAH | c.3262G>A p.D1088N | Missense Mutation (SNP) | VAF 43/411 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPN5 | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.186); called by muse, mutect2
- OR10G3 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- OR11L1 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 27/352 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR1B1 | c.257A>C p.H86P | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by mutect2, varscan2
- OR1L8 | c.493A>C p.N165H | Missense Mutation (SNP) | VAF 33/463 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2
- OR2AG1 | c.550T>G p.L184V | Missense Mutation (SNP) | VAF 21/299 reads (7%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2C3 | c.191T>G p.L64R | Missense Mutation (SNP) | VAF 36/398 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- OR2T11 | c.136A>C p.I46L | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2
- OR4F5 | c.431T>G p.I144S | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2
- OR5D3P | c.483T>G p.S161R | Missense Mutation (SNP) | VAF 31/294 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- OR5M3 | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 36/372 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); called by muse, mutect2
- OR6B1 | c.850A>G p.N284D | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR7D4 | c.505T>C p.S169P | Missense Mutation (SNP) | VAF 34/398 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.114); called by muse, mutect2
- OR9A4 | c.682A>C p.I228L | Missense Mutation (SNP) | VAF 27/382 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2
- OTOA | c.667A>C p.T223P | Missense Mutation (SNP) | VAF 21/246 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2
- OTOA | c.949T>G p.F317V | Missense Mutation (SNP) | VAF 48/423 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OTOG | c.2978A>G p.H993R | Missense Mutation (SNP) | VAF 36/384 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- P2RY2 | c.760T>C p.F254L | Missense Mutation (SNP) | VAF 42/426 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P4HA2 | c.1175A>T p.D392V | Missense Mutation (SNP) | VAF 30/369 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2
- PABPC3 | c.313A>G p.N105D | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2
- PARK7 | c.361A>G p.S121G | Missense Mutation (SNP) | VAF 66/309 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PARPBP | c.1740A>C p.*580Yext*23 | Nonstop Mutation (SNP) | VAF 14/116 reads (12%) | called by muse, mutect2, varscan2
- PATL1 | c.364A>G p.N122D | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.242); called by muse, mutect2
- PCDHA6 | c.1019T>G p.I340S | Missense Mutation (SNP) | VAF 12/299 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- PCDHA8 | c.1820T>C p.L607P | Missense Mutation (SNP) | VAF 40/392 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDHB13 | c.1337A>G p.D446G | Missense Mutation (SNP) | VAF 40/478 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB7 | c.336A>T p.K112N | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2
- PCDHGA5 | c.454T>G p.L152V | Missense Mutation (SNP) | VAF 38/363 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.034); called by muse, mutect2
- PCDHGA7 | c.1222A>G p.K408E | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); called by muse, mutect2
- PCF11 | c.2451T>A p.C817* | Nonsense Mutation (SNP) | VAF 37/440 reads (8%) | called by muse, mutect2
- PCLO | c.14758G>A p.E4920K | Missense Mutation (SNP) | VAF 13/390 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2
- PCLO | c.13070A>C p.N4357T | Missense Mutation (SNP) | VAF 56/345 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCSK2 | c.1496A>C p.N499T | Missense Mutation (SNP) | VAF 29/362 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.041); called by muse, mutect2
- PDCD11 | c.2623A>G p.K875E | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.87); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PDE6C | c.1538A>C p.D513A | Missense Mutation (SNP) | VAF 35/395 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- PDILT | c.326T>G p.L109R | Missense Mutation (SNP) | VAF 32/422 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PEAR1 | c.1361A>G p.E454G | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, mutect2
- PFKL | c.2269A>G p.S757G | Missense Mutation (SNP) | VAF 28/365 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2
- PGAM5 | c.424T>A p.F142I | Missense Mutation (SNP) | VAF 32/271 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- PHACTR2 | c.605A>T p.K202M | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- PHKA1 | c.3459A>C p.K1153N | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- PI3 | c.215A>G p.K72R | Missense Mutation (SNP) | VAF 50/603 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PIEZO2 | c.1868A>T p.E623V | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- PIK3R1 | c.1426-1G>A p.X476_splice (on ENST00000521381 / NM_181523.3; = p.X206_splice on NM_181504.4) | Splice Site (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- PITPNM1 | c.1693G>A p.G565S | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PKHD1 | c.7379A>C p.K2460T | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PKHD1L1 | c.11803G>A p.A3935T | Missense Mutation (SNP) | VAF 29/322 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PLA1A | c.67A>C p.S23R | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- PLA2G3 | c.77G>A p.W26* | Nonsense Mutation (SNP) | VAF 32/465 reads (7%) | called by muse, mutect2
- PLBD1 | c.1310T>A p.F437Y | Missense Mutation (SNP) | VAF 40/418 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLCB1 | c.436A>G p.M146V | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- PLCB4 | c.330T>G p.S110R | Missense Mutation (SNP) | VAF 23/362 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- PLCD4 | c.1358A>C p.E453A | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.058); called by muse, mutect2
- PLCG2 | c.3040T>A p.F1014I | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLEKHD1 | c.1456T>G p.S486A | Missense Mutation (SNP) | VAF 43/401 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PLEKHG4B | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 44/457 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PLEKHO2 | c.1439A>C p.E480A | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2
- PLK1 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLPP4 | c.466T>G p.F156V | Missense Mutation (SNP) | VAF 30/361 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2
- PLPPR4 | c.502T>G p.F168V | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNC1 | c.455A>C p.E152A | Missense Mutation (SNP) | VAF 52/537 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PNMA8B | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 40/370 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- PNPT1 | c.1902A>C p.E634D | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.247); called by muse, mutect2
- POLR1B | c.1205A>G p.K402R | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.565); called by muse, mutect2
- POLR3A | c.1208T>C p.F403S | Missense Mutation (SNP) | VAF 34/344 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.09); called by muse, mutect2
- POPDC2 | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 16/403 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2
- PPP1R3G | c.599T>C p.L200P | Missense Mutation (SNP) | VAF 49/422 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PPP2R2B | c.197A>C p.E66A (on ENST00000394409; = p.E132A on NM_181674.2) | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2
- PPP4R3A | c.1747G>A p.V583I (on ENST00000554943 / NM_001366432.1; = p.V570I on NM_001284280.1) | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2
- PRAG1 | c.1394A>G p.D465G | Missense Mutation (SNP) | VAF 52/506 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- PRKAA1 | c.339T>G p.F113L | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PRKD3 | c.2522T>G p.L841R | Missense Mutation (SNP) | VAF 26/323 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PROK2 | c.61A>G p.T21A | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2
- PRRC2B | c.5291T>C p.V1764A | Missense Mutation (SNP) | VAF 44/502 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2
- PRRT4 | c.992A>C p.E331A | Missense Mutation (SNP) | VAF 22/518 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- PRSS37 | c.522T>G p.N174K | Missense Mutation (SNP) | VAF 22/395 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); called by muse, mutect2
- PRUNE2 | c.2946A>C p.E982D | Missense Mutation (SNP) | VAF 34/364 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2
- PSD3 | c.94T>G p.L32V | Missense Mutation (SNP) | VAF 14/283 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- PSMD5 | c.277A>C p.I93L | Missense Mutation (SNP) | VAF 37/369 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PSTPIP2 | c.914T>C p.L305S | Missense Mutation (SNP) | VAF 15/231 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- PTCHD4 | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- PTCHD4 | c.492T>G p.D164E | Missense Mutation (SNP) | VAF 35/306 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- PTH2R | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTPRN | c.1736T>C p.L579P | Missense Mutation (SNP) | VAF 40/484 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- PTPRN | c.1360A>G p.S454G | Missense Mutation (SNP) | VAF 34/455 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- PTPRN2 | c.2708T>C p.V903A | Missense Mutation (SNP) | VAF 21/383 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PTPRQ | c.4287A>T p.Q1429H (on ENST00000616559; = p.Q1387H on NM_001145026.2) | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2
601 further variants in this file (270 protein-altering or splice-affecting, 277 silent, 54 other) are not listed here.
